Somatic mutation profile of tumor specimen TCGA-DB-A4XA-01A (aliquot TCGA-DB-A4XA-01A-11D-A26M-08) from TCGA case TCGA-DB-A4XA, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Temporal lobe; Tumor grade: G2; Age at diagnosis: 30.7 years (11,195 days).
Specimen TCGA-DB-A4XA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e48856d9-6986-464c-8196-d2826a393a03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4XA-10A (Blood Derived Normal), aliquot TCGA-DB-A4XA-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9228ab53-1f36-415f-a336-f2b8b5534ed6

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Frame Shift Ins 1, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARID1A | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as COSV61378125; called by muse, mutect2, varscan2
- COL6A6 | c.2329dup p.Y777Lfs*3 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | catalogued as rs764240714; called by mutect2, pindel, varscan2
- DDB2 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747222465, COSV57038771; called by muse, mutect2, varscan2
- GRIN2A | c.3889G>A p.D1297N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1431125566, COSV58034185; called by muse, mutect2, varscan2
- MUC16 | c.9083G>T p.S3028I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs139519759, COSV67468264; called by muse, mutect2, varscan2
- OSMR | c.2284A>G p.K762E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV57085544; called by muse, mutect2
- STK31 | c.2339C>A p.A780D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100669056; called by muse, mutect2
- SYNJ2 | c.3269G>A p.R1090H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.77); catalogued as rs141300011; called by muse, mutect2, varscan2
- CIC | c.713_715del p.W238del | In Frame Del (DEL) | VAF 9/50 reads (18%) | called by pindel, varscan2
- IGHA1 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- AATK | c.3711C>T p.D1237= (on ENST00000326724 / NM_001080395.3; = p.D1134= on NM_004920.2) | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs770816664, COSV58367031; called by muse, mutect2, varscan2
